TCGA case TCGA-AO-A126 — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cc0902fd-a2fc-4327-929e-d4219e32e1d7

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 39 years; Vital status: Alive.

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 39.1 years (14,264 days); Year of diagnosis: 2002; Method of diagnosis: Core Biopsy; AJCC pathologic T: T2; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Inner / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 5; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 238 days; Number of cycles: 8; Treatment dose: 7,776 mg; Prescribed dose: 600; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 238 days; Number of cycles: 8; Treatment dose: 520 mg; Prescribed dose: 40; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Recurrent Disease; Days to treatment start: 320 days; Days to treatment end: 1,795 days (4.9 years); Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Goserelin Acetate; Initial disease status: Recurrent Disease; Days to treatment start: 323 days; Days to treatment end: 1,639 days (4.5 years); Route of administration: Subcutaneous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 384 days (1.1 years); Days to treatment end: 421 days (1.2 years); Treatment dose: 10,000 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS). Age at diagnosis: 39.8 years (14,531 days); Days to diagnosis: 267 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.
3. Diagnosis record without a diagnosis name: Age at diagnosis: 39.8 years (14,531 days); Days to diagnosis: 267 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 295 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site, for progressive disease.

Follow-up (3 entries)
- Day 267 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 267 days.
- Days to follow up: 2,850 days (7.8 years); Disease response: Tumor Free.
- Days to follow up: 3,307 days (9.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (FISH): 1.1; Cell count: 30; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): 1.3; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): Copy Number Reported; Copy number: 74; Cell count: 30.
- ERBB2 (IHC): Negative; Staining intensity value: 0; Test value range: <10%.
- ERBB2 (IHC): Negative; Staining intensity value: 1+; Test value range: <10%.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Staining intensity scale: 4 Point Scale; Test value range: 20-29%.
- ESR1 (IHC): Positive; Staining intensity value: 2+; Test value range: 10-19%.
- PGR (IHC): Positive; Staining intensity scale: 4 Point Scale; Test value range: 60-69%.
- PGR (IHC): Positive; Staining intensity value: 2+; Test value range: 10-19%.
- Test (FISH): Copy Number Reported; Copy number: 69; Cell count: 30.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AO-A126-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 450 mg.
  Slide TCGA-AO-A126-01A-01-TSA: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 55; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AO-A126-01A-01-BSA: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 19; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AO-A126-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AO-A126-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Her2 cent17 ratio: 1.1; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: Yes; Er IHC score: 2+; Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Her2 IHC percent positive: <10%; Her2 positivity method text: 3+ Positive; Her2 fish method: >=2.2 Positive; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Inner Quadrant; Anatomic organ subdivision: Right.
- Follow-up form 1: Tumor status: Tumor free; New tumor event surgery: Yes; Er IHC score: 2+; Her2 IHC percent positive: <10%; Her2 IHC score: 0; Her2 positivity method text: 3+ Positive; Her2 copy number: 62; Cent17 copy number: 49; Her2 and cent17 cells count: 31; Her2 cent17 ratio: 1.3; Her2 fish method: >=2.0 Positive; New tumor event surgery met: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Tumor status: Tumor free; New tumor event type: Locoregional Disease; New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event her2 status IHC positive: <10%; New tumor event her2 positivity IHC score: 0; New tumor event cent 17 her2 ratio: 1.3.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4, Route of administrations: Route of administration: PO.
- Drug treatment 5: Regimen number: 1; Pharmaceutical therapy drug name: Zoladex.
- Drug treatment 5, Route of administrations: Route of administration: SC.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,307 days; disease-specific survival: no event (censored), 3,307 days; disease-free interval: event (new tumor event after initially disease-free), 267 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 267 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AO-A126-01A-11D-A10L-01): tumor purity 0.74, ploidy 1.93, whole-genome doublings 0.
